Somatic mutation profile of tumor specimen TCGA-D1-A17K-01A (aliquot TCGA-D1-A17K-01A-11D-A12J-09) from TCGA case TCGA-D1-A17K, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 74.7 years (27,283 days).
Specimen TCGA-D1-A17K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2b1c9c3-937a-458c-9b2b-1d4d082c0d07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17K-10A (Blood Derived Normal), aliquot TCGA-D1-A17K-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0109a73-cf17-43a9-bcc4-1e0b57e7ac44

The open-access MAF lists 74 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 42, Silent 22, Frame Shift Del 5, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 86/121 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.501del p.Q167Hfs*3 | Frame Shift Del (DEL) | VAF 29/44 reads (66%) | catalogued as rs1567553148, COSV52701014, COSV53108662, COSV53327706, COSV53408532; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AKAP9 | c.3999A>C p.K1333N | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV62354393; called by muse, mutect2, varscan2
- ARHGAP20 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 67/156 reads (43%) | catalogued as COSV52816837; called by muse, mutect2, varscan2
- CACNG3 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1047741779, COSV50064727; called by muse, mutect2, varscan2
- CATSPER2 | c.842+1G>C p.X281_splice | Splice Site (SNP) | VAF 9/97 reads (9%) | catalogued as rs199516208, COSV58660954, COSV58661550; called by muse, mutect2
- CCSER2 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV56509846; called by muse, mutect2
- CILP | c.2782C>A p.P928T | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV56024457, COSV56026839; called by muse, mutect2
- CSNK1A1L | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65790021; called by muse, mutect2
- CTXN3 | c.48C>A p.N16K | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV65218699; called by muse, mutect2
- CYP2D6 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.414); catalogued as rs542114265, COSV62245051; called by muse, mutect2, varscan2
- DNAAF5 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV52420039; called by muse, mutect2, varscan2
- DNAH2 | c.4771G>A p.G1591S | Missense Mutation (SNP) | VAF 162/192 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770055899, COSV101209316, COSV66723923; called by muse, mutect2, varscan2
- DOCK10 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs377274433; called by muse, mutect2, varscan2
- ELAVL4 | c.510A>G p.G170= | Splice Region (SNP) | VAF 6/118 reads (5%) | catalogued as COSV63918354; called by muse, mutect2
- FFAR3 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs781407676, COSV59909502; called by muse, mutect2, varscan2
- FHOD3 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV57173957; called by muse, mutect2, varscan2
- FOXA2 | c.730G>T p.E244* (on ENST00000377115 / NM_153675.3; = p.E250* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 18/24 reads (75%) | catalogued as COSV65795534, COSV65796814; called by muse, mutect2, varscan2
- FOXO1 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs149675484, COSV65426623; called by muse, mutect2, varscan2
- GLB1L | c.156C>G p.S52R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55478148; called by muse, mutect2, varscan2
- HID1 | c.1539C>G p.F513L | Missense Mutation (SNP) | VAF 254/284 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59352088; called by muse, mutect2, varscan2
- HIVEP3 | c.2446A>C p.S816R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV56020833; called by muse, mutect2, varscan2
- IMPG2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as COSV51983330; called by muse, mutect2, varscan2
- ITPRID1 | c.87C>G p.S29R | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100086559, COSV60080278; called by muse, mutect2, varscan2
- LIPN | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV68384350; called by muse, mutect2, varscan2
- MAGEB6 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV66872819; called by muse, mutect2, varscan2
- MTUS2 | c.3646G>A p.A1216T (on ENST00000612955 / NM_001366650.1; = p.A195T on NM_015233.6) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101070818, COSV66422671; called by muse, mutect2, varscan2
- MYH7B | c.3448del p.A1150Pfs*45 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs1569058872; called by mutect2, varscan2
- NAA15 | c.2155+1del | Frame Shift Del (DEL) | VAF 169/534 reads (32%) | catalogued as COSV99649986; called by mutect2, pindel, varscan2
- NAV3 | c.3674C>T p.A1225V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV57102383; called by muse, mutect2
- OR6C65 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV65568405, COSV65569172; called by muse, mutect2, varscan2
- PAK3 | c.937C>A p.Q313K (on ENST00000262836 / NM_001324328.2; = p.Q298K on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV53278697; called by muse, mutect2
- PDCD2 | c.605T>G p.I202S | Missense Mutation (SNP) | VAF 193/442 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV51341415; called by muse, mutect2, varscan2
- PDGFA | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV63280336; called by muse, mutect2, varscan2
- POLR1B | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54501989; called by muse, mutect2, varscan2
- PRKAG1 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60293999; called by muse, mutect2
- PRKAR1B | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64319594; called by muse, mutect2, varscan2
- PRKD1 | c.1335A>T p.R445S | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV59579653; called by muse, mutect2, varscan2
- RIMS1 | c.4817A>T p.Q1606L | Missense Mutation (SNP) | VAF 142/307 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53474531; called by muse, mutect2, varscan2
- SLCO1C1 | c.1696T>A p.S566T | Missense Mutation (SNP) | VAF 137/420 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV56877489; called by muse, mutect2, varscan2
- SLITRK3 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53851894; called by muse, mutect2, varscan2
- SPTBN5 | c.8251G>C p.G2751R | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV58025907; called by muse, mutect2, varscan2
- TAAR6 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 161/393 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51584546; called by muse, mutect2, varscan2
- TADA3 | c.484T>A p.C162S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV55029288; called by muse, mutect2, varscan2
- TRAK1 | c.2105G>A p.S702N | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs866079933, COSV59646055; called by muse, mutect2, varscan2
- TUBA1A | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV55498615; called by muse, mutect2, varscan2
- WNK3 | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV63615355; called by muse, mutect2, varscan2
- XK | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV66120656; called by muse, mutect2
- ZNF574 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55905966; called by muse, mutect2, varscan2
- CD1E | c.124dup p.T42Nfs*13 | Frame Shift Ins (INS) | VAF 60/176 reads (34%) | called by mutect2, pindel, varscan2
- LRRFIP1 | c.2187del p.E730Nfs*35 (on ENST00000392000 / NM_001137552.2; = p.E706Nfs*35 on NM_004735.4) | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- STK11IP | c.1947_1953del p.V651Mfs*36 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CHD5 | c.2928C>T p.G976= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as rs377324742, COSV99315523; called by muse, mutect2, varscan2
- CLN8 | c.385C>A p.R129= | Silent (SNP) | VAF 13/317 reads (4%) | catalogued as COSV58671235; called by muse, mutect2
- DDX50 | c.6T>G p.P2= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs565593277, COSV65293090; called by muse, mutect2, varscan2
- DISP3 | c.2211C>A p.V737= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs1267709892, COSV53834637; called by muse, mutect2, varscan2
- DPRX | c.279T>C p.G93= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as COSV64949892, COSV64949984; called by muse, mutect2
- EPB41L2 | c.2289C>T p.T763= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as rs765397502, COSV61357890; called by muse, mutect2, varscan2
- GLMN | c.621A>G p.E207= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as COSV64861293; called by muse, mutect2, varscan2
- IPO9 | c.2799C>A p.A933= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as COSV64235085; called by muse, mutect2, varscan2
- JAG1 | c.558C>T p.T186= | Silent (SNP) | VAF 93/243 reads (38%) | catalogued as rs776616206, COSV54761105; called by muse, mutect2, varscan2
- JAKMIP3 | c.2073C>T p.L691= | Silent (SNP) | VAF 31/37 reads (84%) | catalogued as COSV53823792; called by muse, mutect2, varscan2
- LCA5L | c.108C>T p.G36= | Silent (SNP) | VAF 15/326 reads (5%) | catalogued as rs1199252441, COSV55746011; called by muse, mutect2
- MANSC1 | c.1221C>T p.I407= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as rs375526137; called by muse, mutect2, varscan2
- NOL8 | c.3030G>A p.K1010= | Silent (SNP) | VAF 106/134 reads (79%) | catalogued as rs1554735997, COSV100694460, COSV62636951; called by muse, mutect2, varscan2
- NOTCH1 | c.3471G>A p.G1157= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV53078666; called by muse, mutect2, varscan2
- PAK3 | c.936G>A p.K312= (on ENST00000262836 / NM_001324328.2; = p.K297= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as COSV53278679; called by muse, mutect2
- PCDHB7 | c.1647G>A p.V549= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs782788230, COSV50787455, COSV50801706; called by muse, mutect2
- PCDHGA4 | c.1248T>C p.S416= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV54004617; called by muse, mutect2, varscan2
- PLCE1 | c.4836T>C p.N1612= | Silent (SNP) | VAF 90/130 reads (69%) | catalogued as COSV53365072; called by muse, mutect2, varscan2
- POLI | c.903A>T p.S301= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV54191088; called by muse, mutect2
- PRAMEF20 | c.1221A>G p.L407= | Silent (SNP) | VAF 244/558 reads (44%) | called by muse, mutect2, varscan2
- SERPINB3 | c.814T>C p.L272= | Silent (SNP) | VAF 86/125 reads (69%) | catalogued as rs764001253, COSV52193325; called by muse, mutect2, varscan2
- USP6 | c.505C>T p.L169= | Silent (SNP) | VAF 267/309 reads (86%) | catalogued as COSV51492200; called by muse, mutect2, varscan2
